Gene-level copy-number profile of tumor specimen ALCH-B3BH-TTP1-A from ALCHEMIST case ALCH-B3BH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.5 years (21,380 days).
Specimen ALCH-B3BH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b810040f-5e76-4d4f-821d-5ef4591ceb08.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3BH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/354b7fa7-b05a-4016-b2bd-d9b23ae212f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 904; copy number 1: 17,851; copy number 2: 35,707; copy number 3: 2,753; copy number 4: 1,009; copy number 5: 501; copy number 6: 2; copy number 7: 96; copy number 9: 73; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–1): NOC2L.
- chr5:134,114,681–134,151,865, 1 gene (within-gene range 0–1): TCF7.
- chr7:76,972,679–77,005,774, 3 genes (within-gene range 0–1): AC114737.1, DTX2P1, UPK3BP1.
- chr8:37,784,191–37,965,953, 7 genes (within-gene range 0–1): ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1.
- chr14:90,567,495–90,569,976, 1 gene (within-gene range 0–1): AL096869.1.
- chr15:41,493,393–41,503,551, 1 gene: ITPKA.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:67,819,704–67,873,866, 4 genes: SKOR1, AC009292.2, AC009292.1, RNU6-1.
- chr16:19,012,157–19,012,263, 1 gene (within-gene range 0–1): RNU6-1340P.
- chr19:186,373–583,493, 20 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM, AC009005.1, BSG.
- chr19:10,486,125–10,503,558, 2 genes: KEAP1, AC011461.1.
- chr19:12,643,275–12,758,458, 19 genes: RPL10P16, AC010422.3, MAN2B1, AC010422.5, WDR83, AC010422.8, WDR83OS, AC010422.7, DHPS, AC010422.2, GNG14, FBXW9, AC018761.4, TNPO2, SNORD41, AC018761.1, TRIR, GET3, BEST2.
- chr19:12,784,539–12,787,192, 2 genes (within-gene range 0–1): AC018761.3, MIR5684.
- chr19:12,796,820–12,801,849, 2 genes (within-gene range 0–1): PRDX2, AC018761.2.
- chr22:30,356,635–30,378,658, 1 gene (within-gene range 0–1): CCDC157.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 673 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:17,171,757–17,634,105, 9 genes, copy number 5 (within-gene range 4–5): LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, LAP3, AC006160.1, MED28.
- chr4:17,800,655–17,844,865, 2 genes, copy number 7 (within-gene range 2–7): DCAF16, NCAPG.
- chr4:52,590,960–57,207,459, 105 genes, copy number 5–9 (broad region; genes not listed).
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr5:191,495–1,708,868, 58 genes, copy number 5: LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277.
- chr5:39,284,140–40,269,719, 10 genes, copy number 5: C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P.
- chr6:20,500,175–21,232,404, 4 genes, copy number 5 (within-gene range 4–5): Y_RNA, CDKAL1, AL035090.1, AL513188.1.
- chr19:30,850,975–41,605,984, 481 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:43,446,601–43,479,534, 3 genes, copy number 6–23: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 15,849. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
